Somatic mutation profile of tumor specimen MP2PRT-PARWGN-TMP1-A (aliquot MP2PRT-PARWGN-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PARWGN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.4 years (529 days).
Specimen MP2PRT-PARWGN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0beca4f1-bb54-4810-94bf-f4cbf6632fd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWGN-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWGN-NB1-B-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90b42387-0674-48d9-8cb6-84555ac9589e

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 69/650 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs369316238; called by muse, mutect2, varscan2
- CENPV | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 126/279 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1278192530, COSV55333477; called by muse, mutect2, varscan2
- FGGY | c.28A>G p.R10G | Missense Mutation (SNP) | VAF 184/379 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58026238; called by muse, mutect2, varscan2
- FREM2 | c.5294G>A p.R1765H | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs572540483; called by muse, mutect2, varscan2
- LRRC23 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 218/478 reads (46%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs781881095, COSV50391722; called by muse, mutect2
- RFX8 | c.415G>T p.E139* (on ENST00000646446; = p.E68* on NM_001145664.2 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/412 reads (4%) | catalogued as COSV65181519; called by muse, mutect2
- IGLV4-69 | c.357_359delinsCCATTTTTCCC p.*120Hfs*? | Frame Shift Ins (INS) | VAF 65/228 reads (29%) | called by mutect2*, pindel, varscan2*
- PTPRT | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 346/404 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- TMPRSS4 | c.441-1G>T p.X147_splice | Splice Site (SNP) | VAF 126/316 reads (40%) | called by muse, mutect2, varscan2
- DCST2 | c.1917C>T p.S639= | Silent (SNP) | VAF 20/413 reads (5%) | catalogued as rs367722659; called by muse, mutect2
- KIF27 | c.3363G>T p.V1121= | Silent (SNP) | VAF 77/211 reads (36%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+2854G>T | Intron (SNP) | VAF 304/722 reads (42%) | called by muse, mutect2, varscan2
